Somatic mutation profile of tumor specimen 0DK0AI from CCDI case PBBXTG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell sarcoma, NOS; Tissue or organ of origin: Heart; Age at diagnosis: 12.4 years (4,545 days).
Specimen 0DK0AI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33adc644-e95f-43ff-9298-63a6aadb76b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK0AS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bd22d63-31e4-417d-a98e-d35e6bd003dd

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Intron 4, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBLN2 | c.560G>C p.G187A | Missense Mutation (SNP) | VAF 76/764 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as rs1187952556, COSV54050521, COSV54053362; called by muse, mutect2
- DENND4A | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 133/912 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs934802608; called by muse, varscan2
- GLI3 | c.2944G>A p.G982R | Missense Mutation (SNP) | VAF 42/337 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs751382968, COSV67884756; called by muse, mutect2, varscan2
- OR4N2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 508/2640 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs1185775789, COSV60050197, COSV60054028; called by muse, mutect2, varscan2
- ADRA1B | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 150/1327 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASC3 | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 267/1112 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 28/972 reads (3%) | called by muse, mutect2
- IGSF5 | c.958A>G p.K320E | Missense Mutation (SNP) | VAF 123/1217 reads (10%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- PCMTD2 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 444/1219 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP4R3B | c.2426A>G p.N809S (on ENST00000616407 / NM_001122964.3; = p.N724S on NM_020463.4) | Missense Mutation (SNP) | VAF 80/845 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASGRF1 | c.2225C>G p.P742R | Missense Mutation (SNP) | VAF 133/579 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPLP1 | c.160G>C p.V54L | Missense Mutation (SNP) | VAF 78/556 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.294); called by muse, varscan2
- SGK1 | c.303G>C p.L101F | Missense Mutation (SNP) | VAF 64/2208 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPATA48 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 104/1239 reads (8%) | called by muse, mutect2
- ZFPM2 | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 156/2361 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2
- ZNF516 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 163/291 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BCAS3 | c.1839G>C p.L613= (on ENST00000390652 / NM_001353144.2; = p.L598= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 117/1754 reads (7%) | called by muse, mutect2
- DMBT1 | c.6969C>A p.S2323= (on ENST00000338354 / NM_001377530.1; = p.S1566= on NM_004406.3) | Silent (SNP) | VAF 50/628 reads (8%) | called by muse, mutect2
- HDHD5 | c.522G>A p.R174= (on ENST00000336737 / NM_033070.3; = p.R144= on NM_017829.5) | Silent (SNP) | VAF 243/711 reads (34%) | called by muse, mutect2, varscan2
- KCNMB2 | c.273C>A p.I91= | Silent (SNP) | VAF 103/950 reads (11%) | called by muse, mutect2, varscan2
- PRSS23 | c.102A>T p.A34= | Silent (SNP) | VAF 167/811 reads (21%) | called by muse, mutect2, varscan2
- TTC22 | c.171C>A p.L57= | Silent (SNP) | VAF 50/555 reads (9%) | catalogued as COSV64881405; called by muse, mutect2
- ITIH4 | c.1952-89C>T | Intron (SNP) | VAF 54/147 reads (37%) | catalogued as rs903725381; called by muse, mutect2, varscan2
- MMP26 | c.-145+92794G>A | Intron (SNP) | VAF 314/859 reads (37%) | catalogued as rs1347631260; called by muse, mutect2, varscan2
- PPRC1 | c.4551-13C>T | Intron (SNP) | VAF 216/947 reads (23%) | called by muse, mutect2, varscan2
- TCF12 | c.325+48C>T | Intron (SNP) | VAF 95/265 reads (36%) | called by muse, mutect2, varscan2
- TMED3 | c.*15G>A | 3'UTR (SNP) | VAF 110/482 reads (23%) | called by muse, mutect2, varscan2
